Gene-level copy-number profile of tumor specimen TCGA-AG-3731-01A from TCGA case TCGA-AG-3731, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.5 years (23,923 days).
Specimen TCGA-AG-3731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.ff619800-d854-4253-bf03-41d87bc0e58d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3731-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/285132bf-2cb8-4159-b0a1-c646e2a6dcd2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,708; copy number 2: 34,304; copy number 3: 3,291; copy number 4: 72; copy number 5: 1,227; copy number 6: 166; copy number 7: 34; copy number 8: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3731-01A-11D-1732-01): tumor purity 0.3, ploidy 3.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,443 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:37,379,285–45,895,970, 132 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:79,259,402–92,144,435, 191 genes, copy number 5–7 (broad region; genes not listed).
- chr8:92,699,742–92,879,502, 1 gene, copy number 5 (within-gene range 2–5): FLJ46284.
- chr8:92,765,651–104,589,024, 259 genes, copy number 5–8 (broad region; genes not listed).
- chr8:104,699,479–105,188,606, 5 genes, copy number 5 (within-gene range 3–5): AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1.
- chr8:127,289,817–127,742,951, 7 genes, copy number 5 (within-gene range 3–5): CASC8, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr12:66,767–11,895,377, 442 genes, copy number 5 (broad region; genes not listed).
- chr12:15,107,783–15,348,675, 4 genes, copy number 5: RERG, RERG-IT1, RERG-AS1, METTL8P1.
- chr12:19,724,435–27,014,434, 112 genes, copy number 5–6 (broad region; genes not listed).
- chr20:52,972,358–64,313,132, 290 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,328. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
